Gene-level copy-number profile of tumor specimen TCGA-24-1103-01A from TCGA case TCGA-24-1103, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,583 days).
Specimen TCGA-24-1103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1d325c54-f0d1-4a78-a803-95239abbf8e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1103-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f27a595-1e40-4d37-a651-ecff534865cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,163; copy number 2: 32,746; copy number 3: 9,184; copy number 4: 606; copy number 5: 87; copy number 6: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1103-01A-01D-0428-01): tumor purity 0.96, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:121,194,948–122,310,691, 18 genes, copy number 5: RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1.
- chr7:122,328,469–122,440,388, 1 gene, copy number 5: AC004594.1.
- chr8:137,105,352–141,786,313, 52 genes, copy number 5: RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7.
- chr11:119,976,111–122,025,937, 29 genes, copy number 5–6 (within-gene range 3–6): AP001360.3, LINC02744, AP001360.1, AP001360.2, TRIM29, AP000679.1, OAF, POU2F3, AP001150.1, TLCD5, ARHGEF12, 7SK, GRIK4, ELOCP22, AP004147.1, HMGB1P42, TBCEL, TBCEL-TECTA, TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P.

Autosomal genes at a single copy (total copy number 1): 17,163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
